TCGA case TCGA-3H-AB3S — Mesothelioma (TCGA-MESO)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura; Tissue source site: MD Anderson Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1c848577-c3a4-4830-abfa-549992172396

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: United States; Age at index: 69 years; Vital status: Dead; Days to death: 385 days (1.1 years).

Diagnoses (4)
1. Epithelioid mesothelioma, malignant (the primary disease): ICD-O-3 morphology code: 9052/3; ICD-10 code: C45.0; Tissue or organ of origin: Pleura, NOS; Site of resection or biopsy: Pleura, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.7 years (25,471 days); Year of diagnosis: 2009; Method of diagnosis: Biopsy; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Dasatinib; Days to treatment start: 47 days; Days to treatment end: 79 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 132 days; Days to treatment end: 152 days; Treatment dose: 45 Gy; Treatment outcome: Progressive Disease; Number of fractions: 15; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Erlotinib Hydrochloride; Days to treatment start: 221 days; Days to treatment end: 275 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Gemcitabine; Days to treatment start: 221 days; Days to treatment end: 264 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: Teprotumumab; Days to treatment start: 221 days; Days to treatment end: 271 days; Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: Pleurodesis, NOS, prior to procurement.
2. Prior malignancy of the bladder (histology not recorded by GDC).
   Treatment given: Treatment type: Surgery, NOS.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Basal cell carcinoma, NOS: ICD-O-3 morphology code: 8090/3; Tissue or organ of origin: External ear; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Skin.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Recurrence of diagnosis 1 (Epithelioid mesothelioma, malignant), site: Thorax, NOS. Age at diagnosis: 70.2 years (25,657 days); Days to diagnosis: 186 days; Prior treatment: Yes.

Follow-up (4 entries)
- Day 186 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thorax, NOS; Days to recurrence: 186 days.
- Days to follow up: 385 days (1.1 years); Disease response: With Tumor.
- Imaging anatomic site: Pleura; Imaging suv max: 9.6; Timepoint: Prior to Treatment.
- ECOG performance status: 1; Timepoint: Preoperative.

Molecular and laboratory tests
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.3].

Exposures
- Occupation type: Building Frame and Related Trades Workers.
- Exposure type: Asbestos; Exposure source: Occupational.

Family history
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Leukemia.
- Relative with cancer history: yes; Relationship type: Grandparent; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Parent; Relationship primary diagnosis: Skin Cancer.
- Relative with cancer history: yes; Relationship type: Grandparent; Relationship primary diagnosis: Skin Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3H-AB3S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 170 mg.
  Slide TCGA-3H-AB3S-01A-02-TS2: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 65; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3H-AB3S-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3H-AB3S-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Pleurodesis performed prior: No; Tumor status: With tumor; History asbestos exposure: Yes; Primary occupation: Construction and Extraction.
- Primary pathology: Submitted tumor site: Pleura; Histologic diagnosis: Epithelioid mesothelioma.
- Drug treatment 1: Treatment best response: Clinical Progressive Disease.
- Drug treatment 2: Pharmaceutical therapy drug name: Tarceva; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: R1507; Treatment best response: Clinical Progressive Disease.
- Radiation treatment: Treatment best response: Radiographic Progressive Disease.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Ear; Other malignancy histological type: Basal cell carcinoma.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Mohs surgery.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Transurethral resection.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 385 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 385 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 186 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3H-AB3S-01A-21D-A39Q-01): tumor purity 0.81, ploidy 1.93, whole-genome doublings 0.
